Somatic mutation profile of tumor specimen MP2PRT-PAVYEI-TMP1-A (aliquot MP2PRT-PAVYEI-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVYEI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,698 days).
Specimen MP2PRT-PAVYEI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6d5057c-ad5a-45e0-b3a1-98708c182698.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVYEI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVYEI-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d9f6d31-7502-40d3-b5c6-22b6fff0148c

The open-access MAF lists 33 somatic variants for this specimen: 23 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 18, Silent 10, Nonsense Mutation 4, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1E | c.5068G>A p.E1690K | Missense Mutation (SNP) | VAF 147/659 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.31); catalogued as rs569085430, COSV62390649; called by muse, mutect2
- CC2D1A | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 42/608 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.05); catalogued as rs755662350, COSV100528529, COSV100528735; called by muse, mutect2
- CDH7 | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 127/277 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.87); catalogued as rs749777659, COSV59889883; called by muse, mutect2, varscan2
- CES5A | c.375C>A p.N125K | Missense Mutation (SNP) | VAF 29/367 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51863539; called by muse, mutect2
- DNAJC15 | c.353G>C p.R118T | Missense Mutation (SNP) | VAF 46/255 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as rs773076307; called by muse, mutect2, varscan2
- ETV1 | c.233G>T p.S78I | Missense Mutation (SNP) | VAF 164/348 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV54137781; called by muse, mutect2
- MAGEB6B | c.920T>C p.V307A | Missense Mutation (SNP) | VAF 269/280 reads (96%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs754201266; called by muse, mutect2, varscan2
- MYH6 | c.1943C>T p.T648M | Missense Mutation (SNP) | VAF 33/492 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV62452863; called by muse, mutect2
- MYT1 | c.1681C>T p.R561W | Missense Mutation (SNP) | VAF 32/755 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774892018; called by muse, mutect2
- TLR4 | c.2042C>G p.S681* (on ENST00000355622 / NM_138554.5; = p.S641* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 26/466 reads (6%) | catalogued as COSV62923655, COSV62924232; called by muse, mutect2
- UGT1A4 | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 26/519 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs762367100, COSV100531094, COSV59389879, COSV59396877; called by muse, mutect2
- C8A | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 43/416 reads (10%) | called by muse, mutect2, varscan2
- CAPS2 | c.591G>T p.Q197H | Missense Mutation (SNP) | VAF 20/434 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- CCDC38 | c.1604C>T p.S535L | Missense Mutation (SNP) | VAF 90/378 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CYFIP2 | c.2155-1G>A p.X719_splice (on ENST00000616178 / NM_001291722.2; = p.X694_splice on NM_014376.4) | Splice Site (SNP) | VAF 27/397 reads (7%) | called by muse, mutect2
- FCSK | c.44C>G p.T15S | Missense Mutation (SNP) | VAF 32/292 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- FERMT2 | c.1895T>G p.V632G | Missense Mutation (SNP) | VAF 23/304 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.58); called by muse, mutect2
- IGHV1-46 | chr14:106511113 del TGTCTCTCGCAC | Missense Mutation (DEL) | VAF 9/14 reads (64%) | called by mutect2, varscan2*
- NUTM1 | c.2669C>T p.S890F | Missense Mutation (SNP) | VAF 26/428 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.618); called by muse, mutect2
- PBX1 | c.771C>A p.S257R | Missense Mutation (SNP) | VAF 15/452 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); called by muse, mutect2
- PLPPR1 | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 37/417 reads (9%) | called by muse, mutect2
- SAE1 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 13/395 reads (3%) | called by muse, mutect2
- TSEN34 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 36/701 reads (5%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.63); called by muse, mutect2
- ANO1 | c.2037C>T p.F679= | Silent (SNP) | VAF 134/342 reads (39%) | catalogued as rs1242442575, COSV100303734; called by muse, mutect2, varscan2
- CC2D1A | c.684G>A p.L228= | Silent (SNP) | VAF 40/604 reads (7%) | catalogued as rs764693828, COSV100528528; called by muse, mutect2
- DSG4 | c.2313C>T p.D771= | Silent (SNP) | VAF 49/452 reads (11%) | catalogued as COSV100356549; called by muse, mutect2, varscan2
- EFCAB5 | c.2838C>T p.L946= | Silent (SNP) | VAF 17/377 reads (5%) | catalogued as COSV57932526, COSV57934655; called by muse, mutect2
- EPPK1 | c.1893C>T p.C631= | Silent (SNP) | VAF 18/582 reads (3%) | called by muse, mutect2
- PLD4 | c.876C>T p.F292= | Silent (SNP) | VAF 60/529 reads (11%) | catalogued as rs745725821; called by muse, mutect2, varscan2
- RNF17 | c.2553T>A p.T851= | Silent (SNP) | VAF 55/238 reads (23%) | called by muse, mutect2, varscan2
- TENM3 | c.7398G>A p.S2466= | Silent (SNP) | VAF 31/668 reads (5%) | catalogued as rs1485977049; called by muse, mutect2
- VWA7 | c.2013C>G p.P671= | Silent (SNP) | VAF 35/868 reads (4%) | called by muse, mutect2
- ZFHX3 | c.8982C>T p.F2994= | Silent (SNP) | VAF 91/442 reads (21%) | catalogued as COSV51709886; called by muse, mutect2, varscan2
